Somatic mutation profile of tumor specimen MMRF_2080_1_BM_CD138pos (aliquot MMRF_2080_1_BM_CD138pos_T1_KHS5U_L08142) from MMRF case MMRF_2080, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 48.2 years (17,599 days).
Specimen MMRF_2080_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 530ad737-4e76-4659-8f19-a0ad8dad7fba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2080_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2080_1_PB_Whole_C2_KHS5U_L08143; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35dce45d-2a90-4401-ad03-e77b42476b33

The open-access MAF lists 98 somatic variants for this specimen: 49 protein-altering or splice-affecting, 11 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, 3'UTR 18, Intron 11, Silent 11, RNA 4, Frame Shift Del 2, Nonsense Mutation 2, 3'Flank 2, 5'UTR 2, 5'Flank 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- F5 | c.1160T>C p.I387T | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs118203911, CM032568; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CACNA1B | c.4370G>A p.R1457Q | Missense Mutation (SNP) | VAF 131/417 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1445632261; called by muse, mutect2, varscan2
- CDH9 | c.1391del p.N464Ifs*16 | Frame Shift Del (DEL) | VAF 38/164 reads (23%) | catalogued as COSV50253912; called by mutect2, pindel, varscan2
- CTNND2 | c.1499C>T p.A500V | Missense Mutation (SNP) | VAF 130/390 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.17); catalogued as rs768348550, COSV58886429, COSV58919455; called by muse, mutect2, varscan2
- DLK2 | c.115T>C p.C39R | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.326); catalogued as rs1356000655; called by muse, varscan2
- DUSP2 | c.253C>G p.L85V | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0.103); catalogued as COSV56620804; called by muse, mutect2, varscan2
- FLNC | c.7479G>T p.K2493N | Missense Mutation (SNP) | VAF 140/239 reads (59%) | SIFT tolerated (0.2); PolyPhen benign (0.029); catalogued as rs1166268728; called by muse, mutect2, varscan2
- GSPT1 | c.362+3A>G | Splice Region (SNP) | VAF 10/27 reads (37%) | catalogued as rs1349875036; called by muse, mutect2, varscan2
- IGHV2-70 | c.349G>C p.A117P | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs369551675; called by muse, varscan2
- IGLV3-1 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.341); catalogued as rs61736463; called by muse, varscan2
- IRF3 | c.977T>C p.I326T | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.162); catalogued as rs766332611, COSV55862526; called by muse, mutect2, varscan2
- KCTD9 | c.53T>C p.V18A | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1157990333; called by muse, mutect2
- LETM2 | c.1100C>T p.T367M (on ENST00000379957 / NM_001286819.2; = p.T272M on NM_144652.3) | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.278); catalogued as rs776017169; called by muse, mutect2, varscan2
- PIK3R2 | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.568); catalogued as rs765672206; ClinVar: uncertain significance; called by muse, varscan2
- RGS6 | c.1382C>T p.A461V | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs200728150; called by muse, mutect2, varscan2
- SLC44A5 | c.2024T>C p.V675A | Missense Mutation (SNP) | VAF 76/239 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100901852; called by muse, mutect2, varscan2
- UCK2 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.097); catalogued as rs532450720, COSV100903036; called by muse, mutect2, varscan2
- ZFHX3 | c.9107G>A p.R3036Q | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs749152788, COSV51710000; called by muse, mutect2, varscan2
- CCDC65 | c.1390A>T p.N464Y | Missense Mutation (SNP) | VAF 86/181 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CHIC1 | c.223G>A p.V75I | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- FAM133A | c.281A>C p.K94T | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FAT1 | c.5777A>G p.K1926R | Missense Mutation (SNP) | VAF 75/169 reads (44%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FBXO15 | c.1054C>T p.H352Y | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- GATAD1 | c.4C>T p.P2S | Missense Mutation (SNP) | VAF 71/112 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- GLG1 | c.2063T>C p.I688T | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- GPR4 | c.556G>T p.V186L | Missense Mutation (SNP) | VAF 47/218 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.011); called by muse, mutect2
- GUCY1A1 | c.1352T>C p.V451A | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- HOXD11 | c.892C>T p.Q298* | Nonsense Mutation (SNP) | VAF 97/294 reads (33%) | called by muse, mutect2, varscan2
- IGHV1-69D | c.342C>G p.Y114* | Nonsense Mutation (SNP) | VAF 36/58 reads (62%) | called by muse, varscan2
- IGHV2-70D | c.259A>G p.R87G | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); called by muse, varscan2
- IGHV2-70D | c.224A>C p.D75A | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.049); called by muse, varscan2
- LIN7A | c.508A>G p.K170E | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- LPAR4 | c.397A>C p.S133R | Missense Mutation (SNP) | VAF 74/197 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYF5 | c.627C>A p.N209K | Missense Mutation (SNP) | VAF 11/187 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2
- NEFL | c.308G>T p.S103I | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); called by muse, mutect2
- NLGN1 | c.1753T>C p.Y585H | Missense Mutation (SNP) | VAF 104/344 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- ODF4 | c.670_675dup p.S224_F225dup | In Frame Ins (INS) | VAF 16/116 reads (14%) | called by mutect2, varscan2
- OR5M10 | c.403A>T p.R135W | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PIK3R2 | c.1921G>A p.D641N | Missense Mutation (SNP) | VAF 66/269 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PPP3R2 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 19/304 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.019); called by muse, mutect2
- PRKDC | c.11365A>T p.R3789W | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- PRPS2 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- PTK6 | c.1157T>G p.V386G | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.197); called by muse, mutect2
- SLC18B1 | c.1161-2A>C p.X387_splice | Splice Site (SNP) | VAF 84/153 reads (55%) | called by muse, mutect2, varscan2
- SLITRK4 | c.1844T>G p.V615G | Missense Mutation (SNP) | VAF 77/198 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TENT5C | c.22_35del p.T8Vfs*11 | Frame Shift Del (DEL) | VAF 60/388 reads (15%) | called by mutect2, pindel, varscan2
- UNC5C | c.1050G>C p.K350N | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VASH2 | c.19G>T p.D7Y | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- ZC3H12B | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 53/120 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BCAS1 | c.93C>T p.N31= | Silent (SNP) | VAF 41/101 reads (41%) | catalogued as rs1469184269; called by muse, mutect2, varscan2
- EPHA5 | c.228T>A p.I76= | Silent (SNP) | VAF 30/110 reads (27%) | called by muse, varscan2
- MPDZ | c.3129T>C p.S1043= | Silent (SNP) | VAF 50/150 reads (33%) | called by muse, mutect2, varscan2
- MYO3B | c.1986C>G p.T662= | Silent (SNP) | VAF 7/127 reads (6%) | called by muse, mutect2
- NRCAM | c.330C>T p.S110= (on ENST00000379028 / NM_001371124.1; = p.S104= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as rs546208936, COSV61031669; called by muse, mutect2, varscan2
- NRROS | c.555G>A p.E185= | Silent (SNP) | VAF 73/208 reads (35%) | catalogued as rs1321882771; called by muse, mutect2, varscan2
- PIK3R2 | c.1569G>A p.L523= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as rs1309795760, COSV55850483; called by muse, varscan2
- PNMA5 | c.669T>C p.T223= | Silent (SNP) | VAF 19/59 reads (32%) | called by muse, mutect2, varscan2
- SI | c.2541A>C p.I847= | Silent (SNP) | VAF 12/21 reads (57%) | called by muse, mutect2, varscan2
- SLC5A8 | c.1209G>A p.A403= | Silent (SNP) | VAF 38/107 reads (36%) | catalogued as rs780465977; called by muse, mutect2, varscan2
- TLCD1 | c.75G>A p.A25= | Silent (SNP) | VAF 3/48 reads (6%) | catalogued as rs1316733505; called by muse, mutect2
- ADAM33 | c.2241-65C>T | Intron (SNP) | VAF 43/100 reads (43%) | catalogued as rs181480224; called by muse, mutect2, varscan2
- AGPAT3 | c.*242A>C | 3'UTR (SNP) | VAF 82/206 reads (40%) | called by muse, mutect2, varscan2
- ATG2B | c.-120T>C | 5'UTR (SNP) | VAF 23/44 reads (52%) | catalogued as rs964512838; called by muse, mutect2, varscan2
- C11orf45 | c.*527C>T | 3'UTR (SNP) | VAF 40/164 reads (24%) | catalogued as rs981437475; called by muse, mutect2, varscan2
- C2orf72 | c.*1044C>T | 3'UTR (SNP) | VAF 41/86 reads (48%) | catalogued as rs1306845797; called by muse, mutect2, varscan2
- CAPS2 | c.648+25T>A | Intron (SNP) | VAF 12/35 reads (34%) | called by mutect2, varscan2
- CCDC85C | c.*2578A>G | 3'UTR (SNP) | VAF 18/36 reads (50%) | called by muse, mutect2, varscan2
- CLTC | c.*330del | 3'UTR (DEL) | VAF 23/100 reads (23%) | called by mutect2, pindel, varscan2
- CSRNP3 | c.*5696C>T | 3'UTR (SNP) | VAF 4/84 reads (5%) | called by muse, mutect2
- CTSL | c.*241A>T | 3'UTR (SNP) | VAF 21/38 reads (55%) | called by muse, mutect2, varscan2
- CTXN2 | c.*1285T>A | 3'UTR (SNP) | VAF 11/79 reads (14%) | called by muse, mutect2, varscan2
- CUX1 | c.31-2732C>T | Intron (SNP) | VAF 36/113 reads (32%) | catalogued as rs542072937; called by muse, mutect2, varscan2
- DPP4 | chr2:162077356 A>G | 5'Flank (SNP) | VAF 20/40 reads (50%) | called by muse, mutect2, varscan2
- FAM20C | c.1445+127G>A | Intron (SNP) | VAF 12/23 reads (52%) | called by muse, mutect2, varscan2
- FAM76A | c.*296_*312del | 3'UTR (DEL) | VAF 10/13 reads (77%) | catalogued as rs1350575419; called by muse*, mutect2, varscan2*
- GHR | c.*1026G>T | 3'UTR (SNP) | VAF 9/60 reads (15%) | called by muse, mutect2, varscan2
- IGLL5 | c.-33T>C | 5'UTR (SNP) | VAF 21/50 reads (42%) | catalogued as rs563702127; called by muse, mutect2, varscan2
- KIAA1549L | c.*538G>A | 3'UTR (SNP) | VAF 42/88 reads (48%) | called by muse, mutect2, varscan2
- LTB | c.163-36A>G | Intron (SNP) | VAF 108/298 reads (36%) | catalogued as rs139528542, COSV53000823; called by muse, varscan2
- LTB | c.162+27G>A | Intron (SNP) | VAF 33/83 reads (40%) | called by muse, mutect2, varscan2
- MARCHF5 | c.*2142T>C | 3'UTR (SNP) | VAF 15/52 reads (29%) | called by muse, mutect2, varscan2
- MRRFP1 | n.1482C>T | RNA (SNP) | VAF 10/180 reads (6%) | called by muse, mutect2
- MYO10 | c.21+19347T>G | Intron (SNP) | VAF 7/20 reads (35%) | called by mutect2, varscan2
- NXT2 | c.*1478T>C | 3'UTR (SNP) | VAF 28/72 reads (39%) | called by muse, mutect2, varscan2
- NXT2 | c.*1700T>A | 3'UTR (SNP) | VAF 32/61 reads (52%) | called by muse, mutect2, varscan2
- PIK3R2 | c.1809-74C>A | Intron (SNP) | VAF 18/108 reads (17%) | called by muse, mutect2, varscan2
- RNF103 | c.366+2361C>A | Intron (SNP) | VAF 16/59 reads (27%) | called by muse, mutect2, varscan2
- RTL3 | c.*375C>T | 3'UTR (SNP) | VAF 22/61 reads (36%) | called by muse, mutect2, varscan2
- SLC22A2 | c.1064+98A>C | Intron (SNP) | VAF 67/159 reads (42%) | called by muse, mutect2, varscan2
- SNORA9 | chr7:44984101 A>C | 3'Flank (SNP) | VAF 79/245 reads (32%) | called by muse, mutect2, varscan2
- SPECC1 | chr17:20316816 T>A | 3'Flank (SNP) | VAF 38/115 reads (33%) | called by muse, mutect2, varscan2
- SSPOP | n.5500G>A | RNA (SNP) | VAF 8/28 reads (29%) | catalogued as rs752142123, COSV50489637; called by muse, mutect2, varscan2
- TEX264 | c.*31T>C | 3'UTR (SNP) | VAF 39/160 reads (24%) | called by muse, mutect2, varscan2
- TNRC18P2 | n.937G>A | RNA (SNP) | VAF 7/33 reads (21%) | catalogued as rs1221266535; called by muse, mutect2, varscan2
- TTC3P1 | n.5468A>G | RNA (SNP) | VAF 37/107 reads (35%) | called by muse, mutect2, varscan2
- TUBAL3 | c.*355C>T | 3'UTR (SNP) | VAF 36/90 reads (40%) | catalogued as rs782357332; called by muse, mutect2, varscan2
- VSIG1 | c.*1344G>A | 3'UTR (SNP) | VAF 22/62 reads (35%) | called by muse, mutect2, varscan2
- VTI1A | c.560+68388C>G | Intron (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
